Somatic mutation profile of tumor specimen 0DJR1E from CCDI case PBBXEP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Alveolar soft part sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 13.1 years (4,790 days).
Specimen 0DJR1E: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9947e670-8069-49e1-99d0-0a4ba01b5e40.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJQZD (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cf91fe7-38b5-41c7-99a4-72720d226459

The open-access MAF lists 12 somatic variants for this specimen: 3 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 6, Missense Mutation 3, 3'UTR 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPARGC1A | c.616C>G p.P206A | Missense Mutation (SNP) | VAF 54/721 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.696); catalogued as rs924038259, COSV99337143; called by muse, mutect2
- TBX4 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 51/686 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV53606311, COSV99540756; called by muse, mutect2
- MYH7B | c.3039G>C p.E1013D | Missense Mutation (SNP) | VAF 38/702 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BEND4 | c.765T>C p.N255= | Silent (SNP) | VAF 27/341 reads (8%) | called by muse, mutect2
- CRNKL1 | c.1839A>C p.I613= | Silent (SNP) | VAF 27/852 reads (3%) | called by muse, mutect2
- OSMR | c.1110C>A p.L370= | Silent (SNP) | VAF 54/632 reads (9%) | called by muse, mutect2
- PRDM1 | c.1050C>T p.S350= | Silent (SNP) | VAF 50/734 reads (7%) | called by muse, mutect2
- PURB | c.654G>A p.E218= | Silent (SNP) | VAF 28/350 reads (8%) | catalogued as COSV101194889; called by muse, mutect2
- WFS1 | c.624C>T p.N208= | Silent (SNP) | VAF 63/578 reads (11%) | catalogued as rs759492466; called by muse, mutect2, varscan2
- GRIA2 | c.*3+55C>T | Intron (SNP) | VAF 52/289 reads (18%) | catalogued as rs1218896553, COSV99646098; called by muse, mutect2, varscan2
- MUCL1 | c.*25C>A | 3'UTR (SNP) | VAF 26/466 reads (6%) | called by muse, mutect2
- RSPO2 | c.*12C>T | 3'UTR (SNP) | VAF 50/660 reads (8%) | catalogued as rs375748542, COSV99410454; called by muse, mutect2
